TCGA case TCGA-V4-A9F3 — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e21d8018-8fe9-4c92-8b36-28d7d3f7df2b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 49 years; Year of birth: 1963; Vital status: Dead; Days to death: 873 days (2.4 years); Year of death: 2015.

Diagnoses (4)
1. Epithelioid cell melanoma (the primary disease): ICD-O-3 morphology code: 8771/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.3 years (17,997 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 873 days (2.4 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: >90%; Extrascleral extension present: No; Measurement type: Echographic; Tumor depth measurement: 13; Tumor shape: Dome.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 18.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -8 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 175 days; Number of cycles: 5; Treatment dose: 75 mg/m2; Reason treatment ended: Course of Therapy Completed.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Days to treatment start: 27 days; Days to treatment end: 175 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dacarbazine; Treatment intent type: Salvage; Days to treatment start: 372 days (1.0 years); Days to treatment end: 631 days (1.7 years); Treatment dose: 800 mg/m2; Treatment outcome: No Response; Reason treatment ended: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Sorafenib; Treatment intent type: Salvage; Days to treatment start: 485 days (1.3 years); Days to treatment end: 606 days (1.7 years); Treatment dose: 400 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Epithelioid cell melanoma), site: Liver. Age at diagnosis: 50.2 years (18,326 days); Days to diagnosis: 329 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Epithelioid cell melanoma), site: Liver. Age at diagnosis: 50.2 years (18,352 days); Days to diagnosis: 355 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
4. Metastasis of diagnosis 1 (Epithelioid cell melanoma), site: Skin, NOS. Age at diagnosis: 50.9 years (18,594 days); Days to diagnosis: 597 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 595 days (1.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (8 entries)
- Day 329 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 329 days.
- Days to follow up: 351 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 351 days.
- Days to follow up: 351 days; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 351 days.
- Day 355 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 355 days.
- Days to follow up: 525 days (1.4 years); Disease response: With Tumor.
- Day 597 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 597 days (1.6 years).
- Days to follow up: 670 days (1.8 years); Disease response: With Tumor.
- Days to follow up: 873 days (2.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: p.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 20.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 170 cm; BMI: 30.8.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9F3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 40 mg.
  Slide TCGA-V4-A9F3-01A-01-TS1: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9F3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9F3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 6p gain; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 873 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 873 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 329 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9F3-01A-11D-A39V-01): tumor purity 0.72, ploidy 1.99, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- days to metastasis: 351
- days to outcome: 735
- days to pharm therapy imaging 2: 474
- days to pharm therapy imaging 3: 657
- days to procedure 1: -8
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- drug name 2: deticene
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- number cycles 1: 5
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy dose units 3: mg
- pharm therapy evaluated by imaging 2: Yes
- pharm therapy evaluated by imaging 3: Yes
- pharm therapy imaging type 2: MRI
- pharm therapy imaging type 3: MRI
- pharm therapy status 1: completed as planned
- pharm therapy status 2: treatment discontinued
- pharm therapy status 3: treatment discontinued
- pharm therapy status reason 2: Lack of Response
- pharm therapy status reason 3: Lack of Response
- resection status 1: R0
- site of metastasis: cutaneous, liver
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4a
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
